Somatic mutation profile of tumor specimen TCGA-BS-A0VI-01A (aliquot TCGA-BS-A0VI-01A-11D-A14G-09) from TCGA case TCGA-BS-A0VI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 58.0 years (21,198 days).
Specimen TCGA-BS-A0VI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef80e313-85f2-4cd7-b1c3-3df572b426f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0VI-10A (Blood Derived Normal), aliquot TCGA-BS-A0VI-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/964a3609-13ff-40c2-a353-dbd34eb44bff

The open-access MAF lists 340 somatic variants for this specimen: 266 protein-altering or splice-affecting, 64 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 64, Frame Shift Del 50, Frame Shift Ins 16, Nonsense Mutation 11, Intron 5, Splice Site 5, In Frame Del 4, Splice Region 3, 3'Flank 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- F2 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1227147475, CM940388, COSV100319450; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLNA | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as rs398123614, COSV100774508; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HIBCH | c.129del p.G44Vfs*6 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs767597690; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2B | c.5335C>T p.R1779* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs1568379151, COSV99719269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.482dup p.A162Gfs*15 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, varscan2
- MTM1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs132630305, CM970993, COSV100080338; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 87/112 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTN | c.74761C>T p.R24921* (on ENST00000591111; = p.R17497* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as rs869025545, CM1514737, COSV100604447; ClinVar: likely pathogenic; called by mutect2, varscan2
- ACSM2B | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs372593813; called by muse, mutect2, varscan2
- ADAM23 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs778780969, COSV52215929; called by muse, mutect2, varscan2
- ADAMTS17 | c.2775G>A p.W925* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99170490; called by muse, mutect2, varscan2
- ADAMTS2 | c.1792C>A p.R598S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs374720937, COSV99078638, COSV99281656; called by muse, varscan2
- ADGRB2 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs746636296, COSV57079132, COSV99925780; called by muse, mutect2, varscan2
- ADGRG4 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV99795090; called by muse, mutect2, varscan2
- ADRA1B | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs1273352160, COSV60701265; called by muse, mutect2, varscan2
- AFF3 | c.844T>C p.S282P | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100418511; called by muse, mutect2, varscan2
- AMPD2 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.298); catalogued as COSV56647354; called by muse, mutect2, varscan2
- AMPH | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100341619; called by muse, mutect2, varscan2
- ANK2 | c.8243A>G p.H2748R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV100000854; called by muse, mutect2, varscan2
- ANKRD35 | c.2951T>C p.M984T | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100841687; called by muse, mutect2
- APBB1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs543265186, COSV54979012; called by muse, mutect2, varscan2
- AQP4 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.359); catalogued as rs760876531, COSV67219280; called by muse, mutect2, varscan2
- ARAP2 | c.2015A>T p.E672V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100394393; called by muse, mutect2, varscan2
- ARAP3 | c.4540T>C p.S1514P | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV99499540; called by muse, mutect2
- ARFGEF3 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV99293021; called by muse, mutect2
- ARID1A | c.2296del p.Q766Sfs*67 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as COSV61372766; called by mutect2, pindel, varscan2
- ARMH3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1301593069, COSV64233381; called by muse, mutect2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs746676748; called by mutect2, varscan2
- ATP11A | c.1497del p.K500Nfs*27 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs1566546408, COSV52105595; called by mutect2, pindel, varscan2
- AXL | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs769316836, COSV99996306; called by muse, mutect2, varscan2
- BAZ2A | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs535118194, COSV99465381; called by muse, mutect2, varscan2
- BCAP31 | c.431G>C p.S144T | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.416); catalogued as COSV100798914, COSV61452452; called by muse, mutect2, varscan2
- BFSP2 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.967); catalogued as COSV100183678; called by muse, mutect2, varscan2
- BPNT1 | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100435624; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs763134487; called by mutect2, varscan2
- C19orf12 | c.437C>T p.A146V (on ENST00000392278 / NM_001031726.3; = p.A135V on NM_031448.6) | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV60364185; called by muse, mutect2, varscan2
- C1QL4 | c.497A>G p.D166G | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99226778; called by muse, mutect2, varscan2
- C6orf62 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100015919; called by muse, mutect2, varscan2
- CACNA1F | c.3406G>A p.V1136I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs782039374, COSV100544620; called by muse, mutect2, varscan2
- CAMSAP3 | c.3724A>G p.K1242E | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50337890, COSV99350313; called by muse, mutect2, varscan2
- CAMTA1 | c.4624C>T p.P1542S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV100348170; called by muse, mutect2, varscan2
- CD4 | c.681T>A p.F227L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.666); catalogued as COSV99163738; called by muse, mutect2, varscan2
- CDC42BPA | c.2023C>A p.P675T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs767024673, COSV62003387, COSV62003849; called by muse, mutect2, varscan2
- CDC42BPG | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777210451, COSV61348924; called by muse, mutect2, varscan2
- CHD2 | c.3243G>T p.Q1081H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1255470688, COSV101245045; called by muse, mutect2
- CILP2 | c.3365C>T p.P1122L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs751797078, COSV52272833, COSV52280901, COSV99364217; called by muse, mutect2, varscan2
- CIT | c.426dup p.E143* | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | catalogued as rs763954129; called by mutect2, pindel, varscan2
- CLEC14A | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs369867645; called by muse, mutect2, varscan2
- COBLL1 | c.1688G>A p.G563E (on ENST00000392717; = p.G525E on NM_014900.5) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV99527675; called by muse, mutect2, varscan2
- COL21A1 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55155721, COSV55175198; called by muse, mutect2, varscan2
- CRTC3 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs762501027, COSV99185645; called by muse, mutect2, varscan2
- CSF3R | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs754739637, COSV58970360; called by muse, mutect2, varscan2
- CYBB | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782094658, COSV66084889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX59 | c.1139C>T p.T380I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.331); catalogued as COSV100494494; called by muse, mutect2, varscan2
- DENND1A | c.2198A>G p.D733G | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.366); catalogued as COSV101011912; called by muse, mutect2, varscan2
- DGAT2 | c.523A>G p.S175G | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99929660; called by muse, mutect2, varscan2
- DHRS1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs200961410, COSV99852244; called by muse, varscan2
- DLC1 | c.1849del p.R617Gfs*37 (on ENST00000276297 / NM_001348081.2; = p.R180Gfs*37 on NM_006094.5) | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as COSV52307798; called by mutect2, pindel, varscan2
- DLG5 | c.3577C>T p.R1193W | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1266933581, COSV100967387; called by muse, mutect2, varscan2
- DLGAP4 | c.1762A>G p.T588A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.251); catalogued as COSV100211068; called by muse, mutect2, varscan2
- DLL3 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs867628571, COSV99219000; called by muse, mutect2
- DMXL1 | c.4982dup p.N1661Kfs*13 | Frame Shift Ins (INS) | VAF 16/45 reads (36%) | catalogued as rs1029723468; called by mutect2, varscan2
- DNAH1 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as rs779912625, COSV101325393; called by muse, mutect2, varscan2
- DNAH10 | c.3565G>T p.D1189Y (on ENST00000409039; = p.D1128Y on NM_207437.3) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV68988918; called by muse, mutect2
- DNAH17 | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV101101934; called by muse, mutect2, varscan2
- DNAH3 | c.7424_7426del p.K2475del | In Frame Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs750740868; called by pindel, varscan2
- DNM1L | c.2126G>A p.R709H (on ENST00000549701 / NM_012062.5; = p.R672H on NM_005690.4) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs776702636, COSV56776051; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPF1 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100831452; called by muse, mutect2, varscan2
- DPP9 | c.2071G>T p.G691W (on ENST00000598800; = p.G720W on NM_139159.5) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99505910; called by muse, mutect2, varscan2
- DPY19L1 | c.961-2A>G p.X321_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100204606; called by muse, mutect2, varscan2
- DVL3 | c.1995del p.M666Cfs*2 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs771967735; called by mutect2, pindel, varscan2
- EGFL6 | c.473G>T p.C158F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100789868; called by muse, mutect2
- ELAVL4 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV63916278; called by muse, mutect2
- EPHA8 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752919461, COSV99384593; called by muse, mutect2, varscan2
- EPHB3 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237986709, COSV57807615, COSV57809863; called by muse, mutect2, varscan2
- ERRFI1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547029591, COSV66311413; called by muse, mutect2, varscan2
- FAM135B | c.3572C>T p.T1191M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473329880, COSV99421984; called by muse, mutect2, varscan2
- FAM13C | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.545); catalogued as rs370898940; called by muse, mutect2, varscan2
- FAM151A | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs1422386382, COSV100156837; called by muse, mutect2, varscan2
- FARP1 | c.1217del p.G406Afs*69 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs780478785, COSV60345557; called by mutect2, pindel, varscan2
- FAT2 | c.2467G>A p.G823S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.129); catalogued as rs367860988; called by muse, mutect2, varscan2
- FBXL12 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs199575681; called by muse, mutect2, varscan2
- FKBP7 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV104373096, COSV99247538; called by muse, mutect2, varscan2
- FMNL2 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56499133; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs756304971; called by mutect2, varscan2
- GABRA5 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866250154, COSV100164995, COSV59481039; called by muse, mutect2, varscan2
- GARRE1 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100209253; called by muse, mutect2, varscan2
- GP1BA | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850949; called by muse, mutect2, varscan2
- GPX5 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs371361550; called by muse, mutect2, varscan2
- GPX7 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100790918, COSV63652634; called by muse, mutect2, varscan2
- GREB1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as rs527940948, COSV99302687; called by muse, mutect2, varscan2
- GRIN2B | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772078838, COSV74204997; called by muse, mutect2, varscan2
- GTF2IRD2B | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1465009039; called by mutect2, varscan2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as rs763161381; called by mutect2, pindel, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | catalogued as rs750792116; called by mutect2, varscan2
- GTPBP3 | c.1305G>T p.Q435H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100258827; called by muse, mutect2, varscan2
- HDAC4 | c.2238C>A p.F746L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs753482334, COSV61860486, COSV61869956; called by muse, mutect2, varscan2
- HECTD4 | c.6512A>G p.Q2171R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1316368488, COSV66396651; called by muse, mutect2, varscan2
- HPGD | c.474A>G p.I158M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99640279; called by muse, mutect2, varscan2
- IGF2R | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.988); catalogued as rs759226802, COSV100807182; called by muse, mutect2, varscan2
- IGFBP5 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.021); catalogued as COSV52082083, COSV99288876; called by muse, mutect2, varscan2
- IGKV2-24 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1352090689; called by muse, mutect2, varscan2
- IL12RB2 | c.2166del p.C723Afs*21 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs992968293; called by mutect2, pindel, varscan2
- IL22 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs149366319; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs760925109; called by mutect2, pindel
- INPPL1 | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99996091; called by muse, mutect2, varscan2
- IRAG2 | c.3606+2T>C p.X1202_splice (on ENST00000636465; = p.X247_splice on NM_006152.4 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 11/34 reads (32%) | catalogued as COSV63141543; called by muse, mutect2, varscan2
- IRGC | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.582); catalogued as COSV99746214; called by muse, mutect2, varscan2
- ITGA8 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100959100; called by muse, mutect2, varscan2
- KIAA0232 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1393726291, COSV56925030; called by muse, mutect2, varscan2
- KIAA2026 | c.1589G>A p.S530N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs751066336, COSV101198953; called by muse, mutect2, varscan2
- KIF1C | c.2495A>G p.D832G | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.632); catalogued as COSV100297053; called by muse, mutect2, varscan2
- KLHL15 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as rs748571216, COSV100044100; called by muse, mutect2, varscan2
- KRT12 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs762800966, COSV52429837; called by muse, mutect2, varscan2
- LGI4 | c.1507del p.R503Vfs*66 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs757796693, COSV59533393; called by mutect2, pindel, varscan2
- LINGO1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100796351; called by muse, mutect2, varscan2
- LLPH | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV56982012; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP4 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs746964729, COSV101066492; called by muse, mutect2, varscan2
- MAP3K6 | c.3641C>T p.A1214V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100539256; called by muse, mutect2, varscan2
- MAST4 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as rs774099764, COSV101282526; called by muse, mutect2, varscan2
- MBD6 | c.2012dup p.T672Yfs*45 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs750430563; called by mutect2, varscan2
- MCF2L2 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.641); catalogued as COSV100192004; called by muse, mutect2, varscan2
- MCF2L2 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100192008; called by muse, mutect2, varscan2
- MCOLN3 | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV100352670; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs745891632; called by mutect2, varscan2
- METAP2 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV54148963; called by muse, mutect2
- MID1 | c.904T>A p.C302S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV100452351; called by muse, mutect2, varscan2
- MINDY2 | c.1100A>G p.H367R | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs371997194; called by muse, mutect2, varscan2
- MLYCD | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344757641, COSV99299207; called by muse, mutect2
- MPC2 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607549; called by muse, mutect2, varscan2
- MRC2 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100316098; called by muse, mutect2, varscan2
- MST1 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs766691780, COSV99610692; called by muse, mutect2, varscan2
- MTMR6 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101110749; called by muse, mutect2, varscan2
- MYO15A | c.3587G>A p.G1196D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99232071; called by muse, mutect2, varscan2
- MYO5B | c.3860C>T p.A1287V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as COSV99544317; called by muse, mutect2
- MYSM1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs751390112, COSV101284034; called by muse, mutect2, varscan2
- N4BP1 | c.2235G>T p.Q745H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99285032; called by muse, mutect2, varscan2
- NCAPD2 | c.2508dup p.F837Lfs*11 | Frame Shift Ins (INS) | VAF 30/82 reads (37%) | catalogued as rs772347389; called by mutect2, varscan2
- NCKIPSD | c.172-3dup | Splice Region (INS) | VAF 14/46 reads (30%) | catalogued as rs768132931; called by mutect2, varscan2
- NFATC4 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.401); catalogued as COSV99145110; called by muse, mutect2, varscan2
- NHLH1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1215715491, COSV100131440; called by muse, mutect2, varscan2
- NID2 | c.3922C>T p.R1308W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149983760, COSV99356275; called by muse, mutect2, varscan2
- NLGN3 | c.2348C>T p.T783M (on ENST00000358741 / NM_181303.2; = p.T763M on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); catalogued as rs781776653, COSV100704638; called by muse, mutect2, varscan2
- NMBR | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141190379; called by muse, mutect2, varscan2
- NPR1 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100902010; called by muse, mutect2, varscan2
- NTNG1 | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961731; called by muse, mutect2, varscan2
- NUDT21 | c.662+2T>C p.X221_splice | Splice Site (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100295575; called by muse, mutect2, varscan2
- OBSCN | c.16022C>T p.A5341V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99476013; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs755413956; called by mutect2, varscan2
- OSBP2 | c.1302A>G p.G434= | Splice Region (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100212899; called by muse, mutect2
- OSBPL9 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61874023; called by muse, mutect2, varscan2
- OTUD5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV99331807; called by muse, varscan2
- P3H2 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100077381; called by muse, mutect2, varscan2
- PATZ1 | c.1272-2A>G p.X424_splice | Splice Site (SNP) | VAF 26/55 reads (47%) | catalogued as COSV99315263; called by muse, mutect2, varscan2
- PAX3 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM930570, COSV99286507; called by muse, mutect2, varscan2
- PCDHA3 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100793300; called by muse, varscan2
- PHLPP2 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV62423815; called by muse, mutect2, varscan2
- PIAS1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764996234, COSV51030416, COSV99986783; called by muse, mutect2, varscan2
- PLXNA1 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99302748, COSV99304296; called by muse, mutect2
- PLXNB1 | c.5401C>T p.R1801C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs759846178, COSV56486536; called by muse, mutect2, varscan2
- POT1 | c.547-1G>T p.X183_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as COSV62928343; called by muse, mutect2, varscan2
- PPARGC1A | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as rs200187877; called by muse, mutect2, varscan2
- PPP1R9B | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as rs751381448, COSV100380675; called by muse, mutect2, varscan2
- PPP2R1A | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs1475762998, COSV100436197; called by muse, mutect2, varscan2
- PRXL2A | c.218del p.N73Mfs*4 | Frame Shift Del (DEL) | VAF 34/83 reads (41%) | catalogued as COSV64690809; called by mutect2, pindel, varscan2
- PTGFRN | c.1495A>G p.N499D | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as rs145469544, COSV67799746; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | catalogued as rs778292578; called by mutect2, varscan2
- PWWP2B | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV100535709; called by muse, mutect2, varscan2
- RAB19 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144362151; called by muse, mutect2, varscan2
- RBM41 | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99179777; called by muse, mutect2, varscan2
- ROBO3 | c.571dup p.R191Pfs*61 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, varscan2
- RPL14 | c.494dup p.I166Dfs*6 | Frame Shift Ins (INS) | VAF 25/37 reads (68%) | catalogued as rs1243470255; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD1B | c.759G>T p.Q253H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100987211, COSV65033428; called by muse, mutect2, varscan2
- RXRB | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.739); catalogued as COSV100553738; called by muse, mutect2, varscan2
- SCG3 | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99590857; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs765136101; called by mutect2, pindel
- SEC63 | c.1586del p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs758487924; called by mutect2, varscan2
- SEMA3C | c.370C>G p.R124G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99542713; called by muse, mutect2, varscan2
- SF3B2 | c.2625del p.K875Nfs*59 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs759211171; called by mutect2, varscan2
- SFSWAP | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1306534615, COSV55525577; called by muse, mutect2, varscan2
- SGO2 | c.1837A>G p.R613G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV100764644; called by muse, mutect2, varscan2
- SLITRK4 | c.2017C>T p.H673Y | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV100567260; called by muse, mutect2
- SLITRK4 | c.1675A>G p.K559E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV62022208; called by muse, mutect2
- SMARCA1 | c.2128dup p.M710Nfs*10 | Frame Shift Ins (INS) | VAF 16/101 reads (16%) | catalogued as rs1264581496; called by mutect2, pindel, varscan2
- SMARCA4 | c.4066C>T p.R1356W | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60803420; called by muse, mutect2
- SNRNP200 | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV60488946; called by muse, mutect2
- SPHK2 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99709263; called by muse, mutect2, varscan2
- SPRYD3 | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100036649; called by muse, mutect2
- SPTA1 | c.5993C>T p.A1998V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV100934688; called by muse, mutect2
- SPTBN2 | c.4664G>T p.G1555V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.216); catalogued as COSV100018871; called by muse, mutect2, varscan2
- SRP14 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs200831083, COSV51116053; called by muse, mutect2, varscan2
- SULT1C4 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs750911106, COSV55597757; called by muse, mutect2, varscan2
- TAF6 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV100612666; called by muse, mutect2, varscan2
- TARS3 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV100254481, COSV60107699; called by muse, varscan2
- TBC1D8B | c.2015A>G p.Y672C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs373285363, COSV99344174; called by muse, mutect2, varscan2
- TBRG4 | c.1794C>T p.D598= | Splice Region (SNP) | VAF 19/48 reads (40%) | catalogued as rs1168734326, COSV99345337; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs756457255; called by mutect2, pindel
- TECTA | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99879413; called by muse, mutect2, varscan2
- TERB2 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs554833143, COSV100546545; called by muse, mutect2, varscan2
- THOP1 | c.1927A>G p.S643G | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV100310473; called by muse, mutect2, varscan2
- TMOD3 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100419064; called by muse, mutect2, varscan2
- TNKS2 | c.1047dup p.H350Tfs*16 | Frame Shift Ins (INS) | VAF 12/35 reads (34%) | catalogued as rs1436960698; called by mutect2, pindel, varscan2
- TOP1 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100793758; called by muse, mutect2, varscan2
- TP73 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as COSV100601076; called by muse, mutect2, varscan2
- TRAPPC10 | c.3168del p.F1056Lfs*6 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs35152556; called by mutect2, varscan2
- TRIM73 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100099749; called by muse, mutect2, varscan2
- TROAP | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs757962017, COSV99226777; called by muse, mutect2, varscan2
- TRPM2 | c.3469G>A p.A1157T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs982432965, COSV100307988; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.56318G>A p.G18773D (on ENST00000591111; = p.G11349D on NM_003319.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | PolyPhen benign (0.01); catalogued as COSV100604450; called by muse, mutect2, varscan2
- UBOX5 | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs752379442, COSV99417666; called by muse, mutect2, varscan2
- UGGT1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1473972226, COSV99390533; called by muse, mutect2, varscan2
- UMPS | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228914; called by muse, mutect2, varscan2
- UPK3B | c.626G>A p.R209Q (on ENST00000257632; = p.R154Q on NM_001347684.2) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs955543336; called by muse, mutect2, varscan2
- USP13 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV99830998; called by muse, mutect2, varscan2
- USP24 | c.5647A>G p.I1883V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as COSV53769107; called by muse, mutect2, varscan2
- USP28 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749927512, COSV50169229; called by muse, mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs761528888; called by mutect2, varscan2
- WDR5 | c.437C>A p.S146* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV100681826, COSV62273423; called by muse, mutect2, varscan2
- WRNIP1 | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV101062717; called by muse, mutect2, varscan2
- XPO1 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101294186, COSV101294231; called by muse, mutect2, varscan2
- ZBTB10 | c.1133A>G p.H378R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100990164; called by muse, mutect2, varscan2
- ZBTB45 | c.337_340del p.T113Lfs*209 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1408294871; called by pindel, varscan2
- ZNF217 | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100184362; called by muse, mutect2
- ZNF229 | c.487del p.D163Mfs*6 | Frame Shift Del (DEL) | VAF 35/102 reads (34%) | catalogued as COSV99350982; called by mutect2, pindel, varscan2
- ZNF274 | c.656C>T p.T219I (on ENST00000610905; = p.T114I on NM_016324.3) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as rs1330733486, COSV100464942; called by muse, mutect2, varscan2
- ZNF385D | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs752571574, COSV55752607; called by muse, mutect2, varscan2
- ZNF653 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV99542082; called by muse, mutect2, varscan2
- ZNF98 | c.1380A>C p.K460N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV100757394, COSV63335614; called by muse, mutect2, varscan2
- AICDA | c.400del p.V134Cfs*3 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- ASL | c.68dup p.F24Vfs*49 | Frame Shift Ins (INS) | VAF 34/120 reads (28%) | called by mutect2, pindel, varscan2
- ATP2C1 | c.2596_2598del p.K866del | In Frame Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- CACNA1I | c.2352del p.F784Lfs*63 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- CCT4 | c.1153del p.T385Qfs*13 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- CEP78 | c.403_404dup p.D136Gfs*3 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | called by mutect2, varscan2
- DIRAS3 | c.460del p.S154Vfs*10 | Frame Shift Del (DEL) | VAF 31/106 reads (29%) | called by mutect2, pindel, varscan2
- DOP1A | c.7280del p.N2427Mfs*8 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- EXPH5 | c.3167del p.N1056Ifs*12 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- IGHV3-30 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- IL4 | c.29dup p.L11Sfs*55 | Frame Shift Ins (INS) | VAF 40/136 reads (29%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- JRKL | c.313del p.R105Gfs*22 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- KAT6B | c.1938del p.S647Hfs*7 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- LAMC1 | c.643dup p.L215Pfs*19 | Frame Shift Ins (INS) | VAF 8/85 reads (9%) | called by mutect2, pindel, varscan2
- MIGA1 | c.1393del p.Y465Mfs*9 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- MMP9 | c.1467dup p.S490Lfs*55 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- NCOR2 | c.6478del p.L2160Sfs*69 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- PHACTR4 | c.1848del p.K616Nfs*27 (on ENST00000373839 / NM_001350159.2; = p.K626Nfs*27 on NM_023923.4) | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- PTCHD1 | c.1905del p.K635Nfs*8 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- RBM33 | c.962del p.P321Lfs*45 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- RERE | c.1907_1912del p.V636_K637del | In Frame Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, varscan2
- TFAP2B | c.600del p.V201Ffs*8 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- TGIF1 | c.625_626del p.Q209Efs*57 (on ENST00000330513 / NM_001374396.1; = p.Q229Efs*57 on NM_003244.4) | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by pindel, varscan2
- UHRF1BP1 | c.1997del p.L666Cfs*51 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel, varscan2
- UHRF1BP1 | c.3244del p.V1082Wfs*5 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- XPO5 | c.1327_1329del p.Q443del | In Frame Del (DEL) | VAF 12/49 reads (24%) | called by pindel, varscan2
- ZMAT1 | c.1793dup p.K599Efs*5 | Frame Shift Ins (INS) | VAF 32/88 reads (36%) | called by mutect2, pindel, varscan2
- ABHD17A | c.855C>T p.N285= (on ENST00000292577 / NM_001130111.2; = p.N336= on NM_031213.4) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs754721985; called by mutect2, varscan2
- AC011448.1 | c.666C>A p.P222= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99364533; called by muse, mutect2, varscan2
- ACP6 | c.384C>T p.G128= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs1553212308, COSV100984190; called by muse, mutect2, varscan2
- ARL3 | c.513C>T p.N171= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99589016; called by mutect2, varscan2
- B3GNT5 | c.912T>C p.S304= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100192001; called by muse, mutect2, varscan2
- C1orf159 | c.909C>T p.H303= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as rs777256335, COSV99618319; called by muse, mutect2, varscan2
- C6 | c.2061A>G p.L687= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs372418449; called by muse, mutect2, varscan2
- CACNA1E | c.609G>A p.G203= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV100701918; called by muse, mutect2
- CCDC105 | c.168G>A p.P56= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99479852; called by mutect2, varscan2
- CCRL2 | c.699G>A p.R233= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV100645005; called by muse, mutect2, varscan2
- CDH24 | c.1389C>T p.G463= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs907872388, COSV99943701; called by muse, mutect2, varscan2
- CRTAM | c.927C>A p.I309= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99911923; called by muse, mutect2, varscan2
- CSMD1 | c.2715A>G p.T905= (on ENST00000520002; = p.T904= on NM_033225.6) | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100146339; called by muse, mutect2, varscan2
- DENND6B | c.1707G>A p.T569= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs753746427, COSV100833979; called by muse, mutect2, varscan2
- DNAH5 | c.13407C>A p.T4469= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99447924; called by muse, mutect2
- DTNA | c.618A>G p.L206= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs1477355040, COSV99311993; called by muse, mutect2, varscan2
- EBF3 | c.1557C>T p.Y519= (on ENST00000355311 / NM_001375392.1; = p.Y510= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs147171591; called by muse, mutect2, varscan2
- GIPC3 | c.456C>T p.C152= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs1207082039, COSV59259215; called by muse, mutect2, varscan2
- GRIK1 | c.2283G>A p.T761= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs765904533, COSV100515924, COSV58722099; called by muse, mutect2, varscan2
- HIC1 | c.1596C>A p.T532= (on ENST00000322941 / NM_001098202.1; = p.T513= on NM_006497.4) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99558014; called by muse, mutect2, varscan2
- HOXA13 | c.549C>T p.R183= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1253907337, COSV99763554; called by muse, mutect2
- HSPA12A | c.744G>A p.K248= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100979753, COSV65021653; called by muse, mutect2, varscan2
- IGFL2 | c.165C>T p.D55= (on ENST00000377693 / NM_001135113.2; = p.D66= on NM_001002915.2) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs199772350, COSV66617026; called by muse, mutect2, varscan2
- IGSF9B | c.2860C>A p.R954= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100317104; called by muse, mutect2
- IL6R | c.1011T>C p.N337= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV100690703; called by muse, mutect2, varscan2
- INF2 | c.2460G>T p.R820= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99383714; called by muse, mutect2
- KRI1 | c.1365C>T p.D455= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs755967396, COSV100469939; called by muse, mutect2, varscan2
- LEO1 | c.1398C>T p.G466= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1389275789, COSV100166466; called by muse, mutect2, varscan2
- LHX6 | c.810C>T p.C270= (on ENST00000373755 / NM_001242334.2; = p.C299= on NM_014368.5) | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100493323; called by muse, mutect2, varscan2
- LYG2 | c.492C>A p.P164= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100283618; called by muse, mutect2
- MCTP2 | c.388C>A p.R130= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs371305058, COSV100537390; called by muse, varscan2
- MTOR | c.1032A>G p.G344= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs762523375, COSV100815938; called by muse, mutect2, varscan2
- MUC5B | c.6846C>A p.T2282= | Silent (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2, varscan2
- MYLK | c.1764C>A p.A588= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as COSV100658832; called by muse, mutect2
- MYPN | c.3732C>T p.Y1244= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100589805; called by muse, mutect2, varscan2
- NCAPD3 | c.4047G>A p.L1349= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV101592164, COSV73187884; called by muse, mutect2, varscan2
- NUBP1 | c.573C>T p.H191= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1220429718, COSV99296714; called by muse, mutect2, varscan2
- OBSL1 | c.960C>T p.A320= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV54723223; called by muse, mutect2, varscan2
- OGDHL | c.993C>A p.S331= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100934248; called by muse, mutect2, varscan2
- OSR2 | c.99G>A p.T33= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99882469, COSV99882732; called by muse, mutect2, varscan2
- PCDHGB6 | c.108G>A p.S36= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV99535182; called by muse, mutect2
- PLCH2 | c.1041T>C p.G347= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV99615936; called by muse, mutect2, varscan2
- PPP1R13L | c.2355C>A p.V785= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV62908343; called by mutect2, varscan2
- PTCHD3 | c.1644C>T p.C548= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV101438889; called by muse, mutect2, varscan2
- PTPN18 | c.693G>A p.A231= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs201707177, COSV99447648; called by muse, mutect2, varscan2
- RAD54L | c.1140G>A p.R380= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV100914775; called by muse, mutect2, varscan2
- RAI14 | c.2850T>C p.L950= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99462605; called by muse, mutect2, varscan2
- RUNDC3A | c.1117C>T p.L373= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV99835184; called by muse, mutect2, varscan2
- SH3BP5 | c.960C>T p.S320= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs377480225, COSV53743819, COSV99508181; called by muse, mutect2, varscan2
- SLAMF7 | c.117C>T p.F39= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100833248; called by muse, mutect2, varscan2
- SLC39A5 | c.127C>T p.L43= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99907425; called by muse, mutect2, varscan2
- SLC5A7 | c.817C>T p.L273= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV99886524; called by muse, mutect2, varscan2
- SNX9 | c.171T>C p.V57= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV101093928; called by muse, mutect2, varscan2
- SPEF1 | c.33C>T p.H11= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV101124214; called by muse, mutect2, varscan2
- SUFU | c.720G>A p.R240= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV100882970; called by muse, mutect2, varscan2
- SYTL4 | c.921A>G p.E307= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV52166032; called by muse, mutect2
- TGOLN2 | c.36C>A p.V12= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as rs1399905400, COSV56405790; called by muse, mutect2
- THSD4 | c.1842G>A p.R614= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs1567128387, COSV99965087; called by muse, mutect2, varscan2
- TMEFF2 | c.966C>T p.I322= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs147945335; called by muse, mutect2, varscan2
- TMEM130 | c.234G>A p.P78= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as rs782282547, COSV100228649; called by muse, mutect2, varscan2
- TNFRSF1B | c.378C>T p.C126= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1211030639, COSV66164266; called by muse, mutect2, varscan2
- TRIO | c.4707T>C p.I1569= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV100710191; called by muse, mutect2, varscan2
- WASF3 | c.915C>G p.P305= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV58968727; called by muse, mutect2, varscan2
- ZNF264 | c.951C>T p.C317= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as rs1250227619, COSV99567187; called by muse, mutect2
- ACTRT3 | chr3:169764927 G>A | 3'Flank (SNP) | VAF 16/48 reads (33%) | catalogued as rs1306157402; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826244 ins T | 3'Flank (INS) | VAF 10/50 reads (20%) | catalogued as rs768711387; called by mutect2, varscan2
- AP000769.5 | chr11:65499156 del A | 5'Flank (DEL) | VAF 12/35 reads (34%) | catalogued as rs761315580; called by mutect2, pindel, varscan2
- CEP295 | c.5850+216A>G | Intron (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100292208; called by muse, mutect2, varscan2
- KCNK1 | c.356-16554G>A | Intron (SNP) | VAF 13/72 reads (18%) | catalogued as rs536109220; called by muse, mutect2, varscan2
- PXN | c.831+2035G>A | Intron (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- SYNE2 | c.788-750C>A | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100420123, COSV58361692; called by muse, mutect2, varscan2
- TRIM8 | c.*732G>A | 3'UTR (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100193176; called by muse, mutect2, varscan2
- UIMC1 | c.-3dup | 5'UTR (INS) | VAF 6/66 reads (9%) | catalogued as rs1561879057; called by mutect2, pindel
- WASF3 | c.717-881A>G | Intron (SNP) | VAF 31/98 reads (32%) | catalogued as COSV100098451; called by muse, mutect2, varscan2
